Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4472, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4472-01A (Primary Tumor).

Diagnosis:

Total gastrectomy preparation with a focally poorly differentiated adenocarcinoma of mixed - partly diffuse and partly intestinal - type, with infiltration of the perigastric fatty tissue and penetration of the serosa, as well as five regional lymph node metastases. Resection margins in the region of the mucosa tumor-free..

Tumor classification (in conjunction with the preliminary findings)

Adenocarcinoma of mixed type, 3, pT4 N1 (5/29) L0 V0 R0.

Source: NCI Genomic Data Commons file 4ca93da2-4cb5-45f9-80ee-8777f82d16da (TCGA-CG-4472.3F8827E7-3C47-4CA6-A3BC-CF6252B13498.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).